Somatic mutation profile of tumor specimen TARGET-30-PASFGD-01A (aliquot TARGET-30-PASFGD-01A-01D) from TARGET case TARGET-30-PASFGD, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.9 years (343 days).
Specimen TARGET-30-PASFGD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eedcf400-bec7-4407-94df-fc76bfb3f223.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASFGD-10A (Blood Derived Normal), aliquot TARGET-30-PASFGD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed67b1b3-e6d6-466d-b01d-3b4308f02932

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.6000C>T p.S2000= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs1299291701; called by muse, mutect2
- NCOR2 | c.1494A>G p.Q498= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs3040832, COSV62292834; called by muse, varscan2
